Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD6-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: S8 HCC / S5 CCC

Specimen : Rt liver

Gross Photo :

ICD O-3

Carcinoma, Hepatocellular NOS
817013

Site Liver C22.0

QW 5/19/14

GROSS:

Specimen status: Fresh

Operation: Subsegmentectomy, segment 8

Tumorectomy, segment 5

Organ: Liver

Segment 8 (17.0 x 9.5 x 7.0 cm, 395.0 gm)

Segment 5 (7.6 x 4.1 x 2.0 cm, 65.0 gm)

Gallbladder (13.0 cm in length, 5.0 cm in diameter)

[Liver]

Lesions:

[Mass 1]

Tumor location: Segment 8

Size: 10.0 x 7.0 x 6.0 cm

Cut surface: Encapsulated, pale tan, solid and lobulated mass

Focal necrosis and hemorrhage

Gross type: Multinodular confluent

Extent: Abuts but confined to the capsule

Resection margin: Not involved, grossly (safety margin: 0.2 cm)

[Mass 2]

Tumor location: Segment 8

Size: 2.2 x 2.0 x 2.0 cm

Cut surface: Encapsulated, pale green to tan, solid and lobulated mass

Extensive necrosis and hemorrhage

Gross type: Multinodular confluent

Extent: Abuts but confined to the capsule

Resection margin: Not involved, grossly (safety margin: 1.5 cm)

Remaining parenchyme: Cirrhosis

[Gallbladder]

Serosa: Yellowish pink and smooth

Mucosa: Dark green and velvety

Wall: 0.2 cm in thickness

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of segment 8 [Mass 1] x 4

A1-3, mass of segment 5 [Mass 2] x 3

RM1, resection margin of segment 8 x 1

RM2, resection margin of segment 5 x 1

[page 2 of 3]
L, nontumorous liver parenchyme x 1

GB, gallbladder x 1

MICROSCOPIC:

[Mass 1]

Tumor location: Segment 8

Tumor type: Hepatocellular carcinoma

Edmondson-Steiner grade

The worst: III

The major: II

Histologic type: Trabecular and solid

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No

Gleason's capsule invasion: Present

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

[Mass 2]

Tumor location: Segment 5

Tumor type: Hepatocellular carcinoma

Edmondson-Steiner grade

The worst: III

The major: II

Histologic type: Trabecular and solid

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: No

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

Remaining liver parenchyme: Cirrhosis, active

SPECIAL STAIN: Trichrome reveals fibrotic change of hepatic parenchyme.

NOT reported. Gross:

NOT reported. Gross:

[page 3 of 3]
Pleural fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

Peritoneal fluid, smear, inflammation

liver,ectomy,hepatocellular carcinoma

T56000, P10, M81703

gallbladder,ectomy,chronic cholecystitis,cholesterolosis

T57000, P10, M43005, M55250

DIAGNOSIS:

Liver, segment 8, subsegmentectomy: Hepatocellular carcinoma

Liver, segment 5, tumorectomy: Hepatocellular carcinoma

Gallbladder, cholecystectomy: Chronic cholecystitis
Cholesterolosis

Suggestion :

Source: NCI Genomic Data Commons file f5a699e2-9d49-4fc2-9204-ccb67dfe4539 (TCGA-DD-AAD6.B246AEB4-8035-4114-9F1E-3E076809A896.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).